CCDI case PBCGHM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/00020414-9bae-435d-8b8d-94c0a574fe30

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.7 years (3,536 days).

Biospecimens (4 samples)
- Sample 0DRE0K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DRE0S, 0DRE10 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRGF2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
